Gene-level copy-number profile of tumor specimen C3N-04156-02 (profiled together with C3N-04156-03) from CPTAC case C3N-04156, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 47.5 years (17,362 days).
Specimen C3N-04156-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 794011e5-1e22-491e-a3de-821321b96954.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-04156-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/cedb0d50-a1e3-4b15-bfc1-bc2d57e1ce49

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 93; copy number 1: 5,580; copy number 2: 41,021; copy number 3: 11,805; copy number 4: 170; copy number 5: 42; copy number 6: 25; copy number 7: 43; copy number 9: 28; copy number 11: 11; copy number 13: 20; copy number 15: 32; copy number 26: 19; copy number 32: 12.

Homozygous deletions (total copy number 0; autosomes only): 93 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,112,347–22,552,156, 93 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 232 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:38,498,995–39,261,213, 6 genes, copy number 5–7: AC021713.1, LINC02759, LINC01493, AC021723.2, AC021723.1, RNU6-99P.
- chr11:43,827,517–43,880,726, 1 gene, copy number 7 (within-gene range 2–7): AC087521.2.
- chr11:43,880,811–44,001,157, 6 genes, copy number 7: ALKBH3, SEC14L1P1, ALKBH3-AS1, AC087521.3, C11orf96, AC087521.1.
- chr11:49,081,907–49,124,570, 5 genes, copy number 7: UBTFL7, AC084851.2, AC118273.1, AC118273.2, TRIM77BP.
- chr11:67,735,600–68,272,001, 28 genes, copy number 7: OR7E11P, AP003385.5, AP003385.2, AP003385.4, ALG1L8P, FAM86C2P, ENPP7P7, AP003716.1, LINC02754, RNU6-46P, RPS3AP40, AC004923.1, AC004923.2, AC004923.3, OR7E1P, UNC93B1, ALDH3B1, AC004923.4, NDUFS8, MIR7113, MIR4691, TCIRG1, MIR6753, AP002807.1, CHKA, AP002992.1, KMT5B, C11orf24.
- chr11:68,707,440–69,819,416, 31 genes, copy number 26–32: TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:78,171,249–78,215,232, 2 genes, copy number 6 (within-gene range 1–6): KCTD21, USP35.
- chr11:80,321,620–80,762,826, 4 genes, copy number 6: AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720.
- chr22:39,399,778–39,689,735, 8 genes, copy number 5: TAB1, MGAT3, MGAT3-AS1, MIEF1, AL022312.1, ATF4, RPS19BP1, CACNA1I.
- chr22:40,346,500–43,817,394, 127 genes, copy number 5–15 (broad region; genes not listed).
- chr22:44,413,485–45,010,005, 14 genes, copy number 5 (within-gene range 4–8): Z85994.2, LINC01656, MRPS18CP6, AL023973.1, RTL6, KRT18P23, LINC00207, LINC00229, ANP32BP2, PRR5, PRR5-ARHGAP8, ARHGAP8, PHF21B, Z83838.1.

Autosomal genes at a single copy (total copy number 1): 2,724. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
